Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7394, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7394-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1) LYMPH NODES, LEVEL 2 & 3, RIGHT NECK, EXCISION: 21 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/21).

2) LYMPH NODES, LEVEL 1B AND PERIFASCIAL NODE, LEFT, EXCISION: SALIVARY GLAND AND 2 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/2).

3) LYMPH NODES, LEVEL 2 & 3, LEFT NECK, EXCISION: 26 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/26).

4) LYMPH NODES, LEVEL 1A, NECK, EXCISION: 4 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/4).

5) TONGUE AND RIGHT LEVEL 1, RESECTION: MODERATELY DIFFERENTIATED INVASIVE SQUAMOUS CELL CARCINOMA OF THE TONGUE, 7.5 CM IN GREATEST DIMENSION; ALL SURGICAL MARGINS NEGATIVE FOR MALIGNANCY (TUMOR EXTENDS TO WITHIN 0.3 CM OF RIGHT SURGICAL MARGIN); PERINEURAL INVASION PRESENT; 4 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/4) (SEE COMMENT & SUMMARY FINDINGS).

Upper Aerodigestive Tract and Minor Salivary Glands Carcinoma Summary of Findings:

Specimen Type: total glossectomy & neck lymph node dissection

Tumor Site: tongue

Tumor Size: 7.5 cm in greatest dimension

Histologic Type: squamous cell carcinoma

Histologic Grade: moderately differentiated (grade II/III)

Pathologic Staging (pTMN): IVA

Primary tumor (pT): pT4

Regional Lymph Nodes (pN): pN0

Number examined: 57

Numbered involved: 0

Perineural invasion: present

Bony/Cartilage Invasion: Not evaluable

HPV testing ordered: Yes

[page 2 of 3]
COMMENT: These findings correspond to AJCC pathologic Stage IVA (pT4a, pN0, pMn/a).

Electronically Signed Out by [REDACTED] M.D.

[REDACTED]

CLINICAL DATA

Clinical Features: unspecified

Operator: [REDACTED]

Operative Findings: unspecified

Operative Diagnosis: unspecified

Tissue Submitted: 1) right neck level 2,3, 2) left level 1B and perifascial node, 3) left neck level 2, 3; 4) neck dissection, level 1A; 5) total glossectomy, right level 1.

GROSS DESCRIPTION:

1) SOURCE: Right Neck Level 2, 3

Received fresh, labeled "right neck level 2, 3," per requisition, is a 6.0 x 5.5 x 2.cm portion of partially circumscribed yellow-tan lobular adipose tissue with a nodularity noted on palpation. The dissected lymph nodes are submitted as follows:

Summary of sections: 1A, 9 lymph nodes, 9/1; 1B, 2 lymph nodes, each bisected (1 inked black), 4/1; 1C, 2 lymph nodes each bisected (1 inked black) 4/1; 1D-1I, 1 lymph node, bisected, 2/1 each.

2) SOURCE: Left level 1B and perifascial node

Received fresh labeled "left level 1B and perifascial node", per requisition, is a 5 x 4 x 1.6.cm portion of partially circumscribed yellow-tan lobular adipose tissue with a nodularity noted on palpation. Serial sectioning shows a few circumscribed lymph nodes and a gold-tan trabecular cut surface consistent with a gland. Summary of sections: 2A, 4 lymph nodes, 4/1; 2B, section of gland tissue, 2/1.

3) SOURCE: Left Neck level 2, 3

Received fresh, labeled "left neck level 2, 3" per requisition, is a 5 x 4 x 1.8 cm aggregate of partially circumscribed yellow-tan lobular adipose tissue with a nodularity noted on palpation. Summary of sections: 3A, 5 lymph nodes, 5/1; 3B, 6 lymph nodes, 6/1; 3C, 2 lymph nodes, each bisected, (1 inked black), 4/1; 3D, 2 lymph nodes, each bisected 1 inked black), 4/1; 3E, 4lymph nodes, 4/1; 3F-3G, 1 lymph node, bisected, 2/1 each.

4) SOURCE: Neck dissection level 1A

Received fresh, labeled "neck dissection level 1A", per requisition, is a 4

[REDACTED]

[page 3 of 3]
x 3 x 1.2 cm portion of partially circumscribed, yellow-tan lobular adipose tissue with a nodularity noted on palpation.

Summary of sections: 4A, four lymph nodes, 4/1.

5) SOURCE: Total glossectomy right level 1

Received fresh in a container labeled with the patient's name and "total glossectomy right level 1" is a 224 gram total glossectomy specimen measuring 10.5 cm anterior to posterior by 9 cm from right to left by 6.2 cm from superior to inferior. There are no orientation instructions received along with the specimen. The specimen consists of a grossly identifiable tongue with a pink-tan, shaggy mucosal surface which measures 10.5 cm from anterior to posterior by 6.5 cm from right to left by approximately 3.5 cm superior to inferior. There is a small amount of adjacent pink-tan, shiny mucosa, which is consistent with the floor of the mouth. The surface of the specimen opposite the mucosa is pink-red, shaggy, and consistent with a surgical resection margin. Using anatomic landmarks for orientation, the specimen has been inked in the following manner: anterior is orange, posterior is black, right is red, left is yellow, and inferior is green. The mucosal surface is notable for an ulcerated, friable mass that is present on the right floor of mouth, extending to the lateral aspect of the tongue and measures approximately 7.5 x 5.0 cm in area. Grossly, the mass extends to within 1.0 cm of the right lateral margin and 1.5 cm of the anterior margin. The specimen is serially sectioned to reveal a cheesy, white-yellow mass extending approximately 4.0 cm deep to the ulceration and grossly extending to within 0.7 cm of the inferior inked margin, 0.3 cm of the right inked margin, 0.6 cm of the anterior inked margin, 0.5 cm of the posterior inked margin, and appears widely free of the left inked margin. Representative sections are submitted for evaluation.

Summary of sections: 5A, left anterior mucosal margin and left anterior deep, 3/1; 5B, left lateral mucosal margin and left lateral deep, 2/1; 5C, left hypopharynx margin and left hypopharynx deep, 2/1; 5D, posterior mucosal margin and posterior deep, 2/1; 5E, right hypopharynx margin and hypopharynx deep, 2/1; 5F, right lateral mucosal margin and right lateral deep, 2/1; 5G-H, perpendicular sections of tumor approaching right lateral mucosal margin, 1/1 each; 5I-J, tumor approaching right anterior mucosal margin, 1/1 each; 5K, right anterior deep margin, 1/1; 5L, inferior margin, 1/1; 5M-N, representative sections of mass, 1/1 each; 5O, right floor mass, 1/1; 5P, normal appearing posterior tongue, 1/1; 5Q, normal appearing left lateral tongue, 1/1; 5R, normal appearing anterior tongue, 1/1.

Dictated by [REDACTED] (ASCP) for [REDACTED]

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

Source: NCI Genomic Data Commons file 080b7aeb-c462-4352-b521-535af0ebf705 (TCGA-CR-7394.F9B5D5DE-BF3E-43BA-8800-CD1DEC042D81.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).